Somatic mutation profile of tumor specimen 0DFWAZ from CCDI case PBBRYT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.1 years (5,510 days).
Specimen 0DFWAZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e40daa1f-a09b-49cf-96a3-192c37b58b52.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFWB1 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb37c52d-5200-4f59-96bb-db0a07b32f81

The open-access MAF lists 49 somatic variants for this specimen: 36 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 31, Silent 7, 3'UTR 3, Splice Site 2, 5'UTR 2, Nonsense Mutation 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.94G>T p.D32Y | Missense Mutation (SNP) | VAF 422/922 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs28931588, COSV62687956, COSV62688134, COSV62688665; ClinVar: pathogenic / likely pathogenic /  other; called by muse, mutect2, varscan2
- DDX3X | c.1597C>T p.R533C (on ENST00000399959; = p.R534C on NM_001356.5) | Missense Mutation (SNP) | VAF 334/436 reads (77%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as rs1555954284, COSV67863588, COSV67863748; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRWD1 | c.5773C>G p.L1925V | Missense Mutation (SNP) | VAF 367/888 reads (41%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV60896152; called by muse, mutect2, varscan2
- CCND2 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 342/806 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM144535, CM162083, COSV54223211, COSV54225487, COSV54226876; called by muse, mutect2, varscan2
- CDH16 | c.2314C>T p.R772C | Missense Mutation (SNP) | VAF 371/923 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as rs781254169, COSV55336777; called by muse, mutect2, varscan2
- CSNK2A1 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 62/1371 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV104372005; called by muse, mutect2
- FMN1 | c.2047G>A p.D683N (on ENST00000616417 / NM_001277313.2; = p.D460N on NM_001103184.4) | Missense Mutation (SNP) | VAF 50/1446 reads (3%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.859); catalogued as COSV57925000; called by muse, mutect2
- GBP1 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 385/927 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs368835338; called by muse, mutect2, varscan2
- HERC6 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 415/975 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.131); catalogued as rs766604753, COSV99910542; called by muse, mutect2, varscan2
- MCOLN2 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 345/956 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.155); catalogued as rs774176390, COSV52297999; called by muse, mutect2, varscan2
- MUC5B | c.4222G>A p.A1408T | Missense Mutation (SNP) | VAF 154/446 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.357); catalogued as rs373767452; called by muse, mutect2, varscan2
- MYBPC3 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 348/832 reads (42%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.788); catalogued as rs1019697151, CD086093, COSV99920363; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NPAS2 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 350/880 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.391); catalogued as rs183671025, COSV100177277; called by muse, varscan2
- PCNX4 | c.3267+6G>T | Splice Region (SNP) | VAF 38/410 reads (9%) | catalogued as rs1566519390; called by muse, mutect2
- PTPRQ | c.3713C>T p.S1238F (on ENST00000616559; = p.S1196F on NM_001145026.2) | Missense Mutation (SNP) | VAF 42/824 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV57040889; called by muse, mutect2
- RYR1 | c.6700C>T p.R2234C | Missense Mutation (SNP) | VAF 185/632 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201465595; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC6A20 | c.1129G>A p.V377I | Missense Mutation (SNP) | VAF 229/684 reads (33%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.791); catalogued as rs201747191; called by muse, mutect2, varscan2
- STARD9 | c.5374G>A p.A1792T | Missense Mutation (SNP) | VAF 16/440 reads (4%) | SIFT tolerated (0.47); PolyPhen benign (0.031); catalogued as COSV51905270; called by muse, mutect2
- U2SURP | c.2533C>T p.R845C | Missense Mutation (SNP) | VAF 262/676 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67533408; called by muse, mutect2, varscan2
- CASP12 | c.347G>T p.G116V | Missense Mutation (SNP) | VAF 198/759 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CEP350 | c.853C>T p.L285F | Missense Mutation (SNP) | VAF 110/2063 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CHORDC1 | c.682G>T p.V228F | Missense Mutation (SNP) | VAF 181/499 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); called by mutect2, varscan2
- CRYM | c.387+2T>G p.X129_splice | Splice Site (SNP) | VAF 20/678 reads (3%) | called by muse, mutect2
- DHX58 | c.1349G>A p.C450Y | Missense Mutation (SNP) | VAF 182/684 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FXYD1 | c.99C>A p.Y33* | Nonsense Mutation (SNP) | VAF 241/495 reads (49%) | called by muse, mutect2, varscan2
- HMCN2 | c.3739+2T>C p.X1247_splice | Splice Site (SNP) | VAF 142/355 reads (40%) | called by muse, mutect2, varscan2
- JPH4 | c.1021G>A p.G341R | Missense Mutation (SNP) | VAF 115/264 reads (44%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- KIAA0825 | c.3505C>T p.P1169S | Missense Mutation (SNP) | VAF 48/866 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.306); called by muse, mutect2
- PCDHA8 | c.1489C>T p.R497W | Missense Mutation (SNP) | VAF 263/680 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PRAMEF14 | c.1278T>A p.D426E | Missense Mutation (SNP) | VAF 331/975 reads (34%) | SIFT tolerated (0.27); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PTCH1 | c.1448C>A p.A483E | Missense Mutation (SNP) | VAF 335/852 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RP1 | c.2633A>G p.K878R | Missense Mutation (SNP) | VAF 62/1174 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); called by muse, mutect2
- SLC9C2 | c.2899A>T p.S967C | Missense Mutation (SNP) | VAF 76/738 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- TSHZ3 | c.3083T>C p.M1028T | Missense Mutation (SNP) | VAF 169/1113 reads (15%) | SIFT tolerated (0.82); PolyPhen benign (0); called by muse, mutect2, varscan2
- TXNRD1 | c.691C>T p.Q231* (on ENST00000525566 / NM_001093771.3; = p.Q133* on NM_003330.4) | Nonsense Mutation (SNP) | VAF 351/958 reads (37%) | called by muse, mutect2, varscan2
- ZNF516 | c.328G>T p.G110C | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CRB1 | c.2589A>G p.E863= | Silent (SNP) | VAF 66/1662 reads (4%) | called by muse, mutect2
- CSMD3 | c.3453A>T p.G1151= (on ENST00000297405 / NM_001363185.1; = p.G1047= on NM_052900.3) | Silent (SNP) | VAF 298/1114 reads (27%) | called by muse, varscan2
- EYA1 | c.1032C>T p.Y344= | Silent (SNP) | VAF 359/947 reads (38%) | catalogued as rs778091745, COSV58161038, COSV58163484; ClinVar: likely benign; called by muse, mutect2, varscan2
- FPR1 | c.372T>C p.C124= | Silent (SNP) | VAF 72/1343 reads (5%) | called by muse, mutect2
- MUC16 | c.28317A>G p.S9439= | Silent (SNP) | VAF 66/805 reads (8%) | called by muse, mutect2
- SDC1 | c.888C>T p.G296= | Silent (SNP) | VAF 278/727 reads (38%) | catalogued as rs765400519, COSV54339646; called by muse, mutect2, varscan2
- SYNE1 | c.753G>A p.G251= (on ENST00000367255 / NM_182961.4; = p.G258= on NM_033071.3) | Silent (SNP) | VAF 99/856 reads (12%) | catalogued as rs1259174577; called by muse, mutect2, varscan2
- ANO5 | c.*1333A>G | 3'UTR (SNP) | VAF 30/121 reads (25%) | catalogued as rs1054247822; called by muse, mutect2, varscan2
- BBS2 | c.*7A>G | 3'UTR (SNP) | VAF 46/582 reads (8%) | called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 13/220 reads (6%) | called by muse, mutect2
- NPC1 | c.-48C>T | 5'UTR (SNP) | VAF 60/123 reads (49%) | called by muse, mutect2, varscan2
- SYT8 | c.-29C>T | 5'UTR (SNP) | VAF 148/450 reads (33%) | catalogued as rs1009036199; called by muse, mutect2, varscan2
- TEAD1 | c.*20T>C | 3'UTR (SNP) | VAF 20/396 reads (5%) | called by muse, mutect2
